Gene-level copy-number profile of tumor specimen MP2PRT-PAPNWT-TMP1-A from MP2PRT case MP2PRT-PAPNWT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (567 days).
Specimen MP2PRT-PAPNWT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4fc3ce41-2977-4953-9a3e-6d832ae721fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPNWT-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/588ea35a-8915-4cc1-8145-3a80682217d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 625; copy number 2: 28,987; copy number 3: 3,451; copy number 4: 25,005; copy number 5: 779; copy number 6: 23; copy number 7: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 828 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–144,068,350, 22 genes, copy number 7: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr11:134,985,683–135,075,908, 2 genes, copy number 5–7: AP003062.1, LINC02684.
- chr12:31,853,021–31,893,702, 2 genes, copy number 5: AC023050.3, AC023050.4.
- chr12:133,181,409–133,238,549, 5 genes, copy number 6 (within-gene range 4–6): ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr14:18,333,726–19,848,263, 76 genes, copy number 5 (broad region; genes not listed).
- chr14:22,197,446–22,482,959, 13 genes, copy number 6 (within-gene range 4–6): AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr21:13,038,160–25,361,868, 179 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:25,880,550–46,691,226, 528 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
